Somatic mutation profile of tumor specimen TCGA-DB-A4XC-01A (aliquot TCGA-DB-A4XC-01A-11D-A26M-08) from TCGA case TCGA-DB-A4XC, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Temporal lobe; Tumor grade: G2; Age at diagnosis: 26.6 years (9,705 days).
Specimen TCGA-DB-A4XC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a03958af-13ca-4e2b-be0f-9d107d4860b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A4XC-10A (Blood Derived Normal), aliquot TCGA-DB-A4XC-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a9280f6-b4bc-4482-82b9-ba32ce1d91cd

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Frame Shift Del 3, Silent 3, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC139530.2 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV61267123; called by muse, mutect2, varscan2
- DTX1 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV57496322; called by muse, mutect2, varscan2
- EMSY | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58258572; called by muse, mutect2, varscan2
- FAM166B | c.208_210del p.P70del | In Frame Del (DEL) | VAF 18/140 reads (13%) | catalogued as rs1199997622; called by mutect2, pindel, varscan2
- IL17F | c.33G>T p.M11I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as COSV60233851; called by muse, mutect2, varscan2
- MYH13 | c.5291C>T p.T1764M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs192011217, COSV52823570; called by muse, mutect2, varscan2
- RASGRP4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV53094667, COSV99498562; called by muse, mutect2
- RPS6KL1 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63580867; called by muse, mutect2, varscan2
- SSTR4 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV54797574; called by muse, mutect2, varscan2
- TIE1 | c.2953G>A p.V985M | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65249038; called by muse, mutect2, varscan2
- TMEM161B | c.457T>C p.F153L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.476); catalogued as COSV56930062; called by muse, mutect2, varscan2
- TP53 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 53/80 reads (66%) | catalogued as COSV52677652, COSV52734727, COSV52787469, COSV53371041; called by muse, mutect2, varscan2
- ATRX | c.2656_2659del p.E886Lfs*18 | Frame Shift Del (DEL) | VAF 44/68 reads (65%) | called by mutect2, varscan2
- CNOT1 | c.2723_2726del p.K908Sfs*4 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- ERAP1 | c.2575_2578del p.K859Lfs*12 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- TADA2A | c.116T>C p.F39S | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- GLDN | c.1158G>A p.G386= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PCDHGA1 | c.558C>T p.A186= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1192623937, COSV65295651; called by muse, mutect2, varscan2
- TFAP2B | c.1281C>G p.G427= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV53826348; called by muse, mutect2, varscan2
